Somatic mutation profile of tumor specimen TCGA-86-7711-01A (aliquot TCGA-86-7711-01A-11D-2063-08) from TCGA case TCGA-86-7711, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.4 years (25,719 days).
Specimen TCGA-86-7711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 083ba3f9-a51e-4150-95c1-6cb1a014f72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7711-10A (Blood Derived Normal), aliquot TCGA-86-7711-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96dfac91-0f8f-4ae7-86ea-77092d3159c4

The open-access MAF lists 242 somatic variants for this specimen: 182 protein-altering or splice-affecting, 55 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 55, Nonsense Mutation 15, Frame Shift Del 9, Splice Region 4, Intron 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.058); catalogued as COSV52228611; called by muse, mutect2
- AC013489.1 | c.1600A>G p.R534G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV51553177; called by muse, mutect2
- ACSBG1 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51909857; called by muse, mutect2
- ADAM28 | c.1719G>C p.L573F | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV56104366; called by muse, mutect2, varscan2
- ADARB1 | c.1693G>T p.V565L (on ENST00000360697 / NM_001346687.2; = p.V525L on NM_001112.4) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62342239, COSV62347441; called by muse, mutect2, varscan2
- ADGRB3 | c.3841G>T p.V1281L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV53257465; called by muse, mutect2, varscan2
- ADGRE2 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV59691857, COSV59695880; called by muse, mutect2
- ADGRE5 | c.1419T>A p.D473E (on ENST00000242786 / NM_078481.4; = p.D380E on NM_001784.5) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54414232; called by muse, mutect2, varscan2
- ADPRHL1 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60262376; called by muse, mutect2, varscan2
- AMHR2 | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57686753; called by muse, varscan2
- ANKRD13C | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.716); catalogued as rs574863853, COSV52034383; called by muse, mutect2, varscan2
- ARHGAP10 | c.1116T>A p.A372= | Splice Region (SNP) | VAF 11/76 reads (14%) | catalogued as COSV60605297; called by muse, mutect2, varscan2
- ARPC2 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as COSV55286280; called by muse, mutect2, varscan2
- ASB17 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52411798; called by muse, mutect2, varscan2
- ATP10A | c.2839A>T p.K947* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV63522548; called by muse, mutect2, varscan2
- ATP1A4 | c.1835G>T p.C612F | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV63628187; called by muse, mutect2, varscan2
- BPIFA2 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV53612438; called by muse, mutect2, varscan2
- BTBD16 | c.361A>T p.R121W | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53266511; called by muse, mutect2, varscan2
- C12orf71 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV101460520; called by muse, mutect2, varscan2
- C17orf98 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs773702400; called by muse, mutect2
- C1QL2 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV55607482; called by muse, mutect2, varscan2
- C3AR1 | c.264G>C p.W88C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50822990, COSV50825115; called by muse, mutect2
- C7orf31 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52219637; called by muse, mutect2, varscan2
- CAND2 | c.2554C>T p.Q852* (on ENST00000456430 / NM_001162499.2; = p.Q759* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99929089; called by muse, mutect2
- CARD6 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV54565204; called by muse, mutect2
- CCDC170 | c.1806G>T p.M602I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53345093; called by muse, mutect2, varscan2
- CGN | c.2187G>T p.Q729H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV54972875; called by muse, mutect2, varscan2
- CHCHD5 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61424770; called by muse, mutect2
- CHRD | c.2702G>T p.R901I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV52611793; called by muse, mutect2, varscan2
- CLCA1 | c.655T>A p.Y219N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52330550; called by muse, mutect2, varscan2
- CMYA5 | c.3491C>G p.T1164S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV71408994; called by muse, mutect2, varscan2
- COL12A1 | c.1745C>G p.S582* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV59405568; called by muse, mutect2, varscan2
- CPEB1 | c.1251G>A p.M417I (on ENST00000617958; = p.M282I on NM_001079533.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55621048; called by muse, mutect2, varscan2
- CSMD3 | c.9729G>C p.R3243S (on ENST00000297405 / NM_001363185.1; = p.R3074S on NM_052900.3) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1208860784, COSV52291849; called by muse, mutect2
- CYB5R4 | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV63750536; called by muse, mutect2, varscan2
- DAO | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57324098; called by mutect2, varscan2
- DEPDC1B | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54012595; called by muse, mutect2, varscan2
- DIP2B | c.3469G>C p.D1157H | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588023, COSV56590625; called by muse, mutect2, varscan2
- DSG4 | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1468161213, COSV57396510; called by muse, mutect2, varscan2
- DTNA | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52021709; called by muse, mutect2, varscan2
- DYNC2H1 | c.6136C>A p.Q2046K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV62096083, COSV62104301; called by muse, mutect2, varscan2
- DYRK4 | c.192G>C p.W64C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50538867, COSV50543589; called by muse, mutect2, varscan2
- EXPH5 | c.4147A>T p.K1383* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV56207301; called by muse, mutect2, varscan2
- EXTL3 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV55040086; called by muse, mutect2, varscan2
- FAM47B | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV100264315; called by muse, mutect2, varscan2
- FAM47B | c.1590G>T p.R530S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV100264316; called by muse, mutect2, varscan2
- FAM91A1 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.98); catalogued as COSV58239133; called by muse, mutect2, varscan2
- FAT4 | c.11389G>T p.G3797* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100626803, COSV58673045, COSV58704036; called by muse, mutect2, varscan2
- FBXO48 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs748214004, COSV58148131; called by muse, mutect2, varscan2
- FLG | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs756351291, COSV64235927; called by muse, mutect2
- FOXD4L1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV99380521; called by muse, mutect2, varscan2
- FOXM1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV61207327; called by muse, mutect2, varscan2
- GPC6 | c.849C>G p.D283E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV65532987; called by muse, mutect2, varscan2
- GRIA4 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV56915438; called by muse, mutect2, varscan2
- HCN1 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100298999, COSV57533136; called by muse, mutect2, varscan2
- HGF | c.1755C>G p.A585= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as COSV55955427; called by muse, mutect2, varscan2
- HTR3B | c.243T>G p.S81R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as COSV52747128; called by muse, mutect2, varscan2
- IBTK | c.2858T>C p.V953A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1230484550, COSV60395524; called by muse, mutect2
- IGLV1-40 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | catalogued as rs761496206; called by muse, mutect2
- IMMP2L | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59265104; called by muse, mutect2
- IMPG2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV51984248; called by muse, mutect2, varscan2
- INO80D | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68959875; called by muse, mutect2
- IQGAP1 | c.2850G>T p.M950I | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV99184983; called by muse, varscan2
- IQGAP1 | c.2851A>T p.I951L | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51590318; called by muse, varscan2
- KAT7 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV52016543; called by muse, mutect2, varscan2
- KCND3 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56188137; called by muse, mutect2, varscan2
- KIAA1755 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54079859; called by muse, mutect2, varscan2
- KIFC2 | c.1793C>G p.S598C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56762636; called by muse, mutect2
- KLHL25 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100563575; called by muse, mutect2
- KLHL5 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV54678137; called by muse, mutect2, varscan2
- KRT79 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV57941937; called by muse, mutect2, varscan2
- LACRT | c.126A>T p.E42D | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.87); catalogued as COSV57688644; called by muse, mutect2, varscan2
- LEXM | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64023970; called by muse, mutect2
- LIMA1 | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57968044; called by muse, mutect2, varscan2
- LPA | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.988); catalogued as rs770166561, COSV100306962; called by muse, mutect2, varscan2
- LRP6 | c.3355G>T p.A1119S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV99743288; called by muse, mutect2, varscan2
- LRRN3 | c.1753C>G p.P585A | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV57823245; called by muse, mutect2
- M1AP | c.1087C>A p.L363M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.9); catalogued as COSV51847638; called by muse, mutect2, varscan2
- MADD | c.3018G>T p.K1006N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.65); catalogued as COSV60629051; called by muse, mutect2, varscan2
- MAGEL2 | c.2344A>C p.T782P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV58568753; called by muse, mutect2, varscan2
- MAPK4 | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV68543512; called by muse, mutect2
- MAPKAPK5 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV73436133; called by muse, mutect2, varscan2
- MARCHF7 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV52030920; called by muse, mutect2, varscan2
- MARCO | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV59057727; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MKS1 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV58302566, COSV58305804; called by muse, mutect2, varscan2
- MUC17 | c.7489C>G p.P2497A | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60300578; called by muse, mutect2, varscan2
- MUC4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.301); catalogued as COSV62143731; called by muse, mutect2, varscan2
- NDUFA10 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53156222; called by muse, mutect2, varscan2
- NFATC1 | c.2091C>T p.N697= | Splice Region (SNP) | VAF 7/45 reads (16%) | catalogued as rs772857723, COSV53707821, COSV99501831; called by muse, mutect2, varscan2
- NLRP11 | c.936del p.F313Lfs*37 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV64086497; called by mutect2, pindel, varscan2
- NOM1 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV51982128; called by muse, mutect2, varscan2
- NOTCH4 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs776703710, COSV66683270; called by muse, mutect2, varscan2
- NRXN3 | c.1399C>T p.R467C (on ENST00000335750 / NM_001330195.2; = p.R94C on NM_004796.6) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777755848, COSV59775195; called by muse, mutect2, varscan2
- NTRK3 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV58117477, COSV58139159; called by muse, mutect2
- OFD1 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.269); catalogued as COSV60797064; called by muse, mutect2, varscan2
- OR10Q1 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV57471706; called by muse, mutect2, varscan2
- OR10R2 | c.783C>A p.C261* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV63769299, COSV63769398; called by muse, mutect2, varscan2
- OR2F1 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV67331930, COSV67331941; called by muse, mutect2, varscan2
- OR2M5 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs763843528, COSV63546903; called by muse, mutect2, varscan2
- OR51V1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV58316176; called by muse, mutect2, varscan2
- PAOX | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374298; called by muse, mutect2, varscan2
- PAPPA2 | c.2774A>T p.E925V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV62809189; called by muse, mutect2, varscan2
- PATL1 | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.675); catalogued as COSV55692303; called by muse, mutect2, varscan2
- PI4KA | c.3708G>T p.W1236C | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55420630; called by muse, mutect2, varscan2
- PIEZO2 | c.6688C>A p.P2230T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53289161; called by muse, mutect2, varscan2
- PIK3CG | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100782863, COSV63251419; called by muse, mutect2, varscan2
- PKN1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV52876253; called by muse, mutect2, varscan2
- PLCZ1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs760497052, COSV56857749; called by muse, mutect2, varscan2
- PNPT1 | c.1674+1G>T p.X558_splice | Splice Site (SNP) | VAF 29/72 reads (40%) | catalogued as COSV53179586; called by muse, mutect2, varscan2
- POGLUT3 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV60213935; called by muse, mutect2, varscan2
- POLD4 | c.297C>T p.C99= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56745149; called by muse, mutect2
- POLL | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV54577336; called by muse, mutect2, varscan2
- POLQ | c.5546G>A p.R1849Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs376715818; called by muse, mutect2, varscan2
- PSMB1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV51531731; called by muse, mutect2, varscan2
- PTPRD | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100646674, COSV61975384; called by muse, mutect2, varscan2
- PTPRZ1 | c.4982A>G p.Y1661C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66444156; called by muse, mutect2, varscan2
- RAD51AP2 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.068); catalogued as COSV101208311, COSV67588955; called by muse, mutect2, varscan2
- RALGAPA2 | c.3378A>T p.E1126D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV52508714; called by muse, mutect2
- RALGAPB | c.2474A>T p.H825L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV53443120; called by muse, mutect2, varscan2
- RFPL3 | c.359T>A p.M120K (on ENST00000249007 / NM_001098535.1; = p.M91K on NM_006604.2) | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50752431; called by muse, mutect2, varscan2
- RNASEH1 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV59439560; called by mutect2, varscan2
- RSPO1 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV62975162; called by muse, mutect2, varscan2
- SCAF8 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65793511, COSV65794637; called by muse, mutect2, varscan2
- SGCG | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV54567345; called by muse, mutect2, varscan2
- SH2D3C | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201637826, COSV59128654; called by muse, mutect2, varscan2
- SLC16A1 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63710157; called by muse, mutect2, varscan2
- SLC2A4RG | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV55513929; called by muse, mutect2
- SLC32A1 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs772822378, COSV54148043, COSV54148124; called by muse, varscan2
- SLC44A5 | c.1279A>G p.T427A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV63773011; called by muse, mutect2, varscan2
- SMARCA4 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV60803632, COSV60806378; called by muse, mutect2
- SMARCC2 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV57223866; called by muse, mutect2, varscan2
- SNUPN | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV57949377; called by muse, mutect2, varscan2
- SNX2 | c.110C>G p.S37* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV65348935; called by muse, mutect2, varscan2
- SOGA1 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52928608; called by muse, mutect2, varscan2
- SPACA3 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV52192384; called by muse, mutect2, varscan2
- SPAG7 | c.575-2A>T p.X192_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV99236490; called by muse, mutect2, varscan2
- SPTA1 | c.2933G>C p.G978A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as COSV100934726, COSV63758087; called by muse, mutect2
- STRN3 | c.1271G>T p.G424V (on ENST00000357479 / NM_001083893.2; = p.G340V on NM_014574.4) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62581477; called by muse, mutect2, varscan2
- SYNE1 | c.3701G>C p.C1234S (on ENST00000367255 / NM_182961.4; = p.C1241S on NM_033071.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55077552; called by muse, mutect2, varscan2
- TAF2 | c.986T>A p.L329H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65420425; called by muse, mutect2
- TBX15 | c.1579A>T p.R527W (on ENST00000369429 / NM_001330677.2; = p.R421W on NM_152380.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52875258; called by muse, mutect2
- TGM6 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs766380908, COSV52479717; called by muse, mutect2, varscan2
- TMC4 | c.1976T>G p.L659R (on ENST00000617472 / NM_001145303.3; = p.L653R on NM_144686.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55828557; called by muse, mutect2
- TMEM202 | c.313T>C p.W105R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100499159; called by muse, mutect2
- TMEM202 | c.314G>T p.W105L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100499161; called by muse, mutect2
- TMPRSS11D | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52225621; called by muse, mutect2, varscan2
- TNKS | c.2775T>A p.H925Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV60065043; called by muse, mutect2, varscan2
- TNRC18 | c.4805A>G p.H1602R | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs769752891, COSV68169616; called by muse, varscan2
- TRHDE | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs771688480, COSV53831518; called by muse, mutect2, varscan2
- TSKU | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100290085; called by muse, mutect2, varscan2
- TSPAN33 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs142211237; called by muse, mutect2, varscan2
- UBE2O | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60066995; called by muse, mutect2
- UBN1 | c.1443G>C p.E481D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as rs1210929461, COSV52168533, COSV52171809; called by muse, mutect2
- UGT3A2 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs199567567; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.941); catalogued as COSV51959509; called by muse, mutect2, varscan2
- UTRN | c.7796A>G p.Y2599C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as rs938523044, COSV62310111; called by muse, mutect2, varscan2
- VAV1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58384289; called by muse, mutect2, varscan2
- VAX2 | c.856A>T p.K286* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV52267097; called by muse, mutect2, varscan2
- WDFY3 | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55711917; called by muse, mutect2, varscan2
- WDR38 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV62019401; called by muse, mutect2, varscan2
- WWOX | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV68366195; called by muse, mutect2, varscan2
- ZDBF2 | c.2298T>A p.H766Q | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65629294; called by muse, mutect2, varscan2
- ZFHX4 | c.8572G>T p.E2858* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV51490543; called by muse, mutect2
- ZIC4 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs916708888, COSV67172681, COSV67173104; called by muse, mutect2, varscan2
- ZNF223 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV71572071; called by muse, mutect2, varscan2
- ZNF236 | c.4717G>C p.D1573H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53495923; called by muse, mutect2, varscan2
- ZNF519 | c.1565del p.G522Afs*15 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as COSV73913264; called by mutect2, pindel, varscan2
- ZNF675 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs755480438, COSV63097306; called by muse, varscan2
- ZNF675 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV63097314; called by muse, varscan2
- ZRANB1 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV62843791; called by muse, mutect2, varscan2
- AHNAK2 | c.3065_3081del p.D1022Gfs*18 | Frame Shift Del (DEL) | VAF 30/246 reads (12%) | called by mutect2, pindel
- DOCK5 | c.2136_2157del p.F712Lfs*13 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.9311A>T p.K3104M | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- FER1L6 | c.998del p.D333Afs*2 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- MED24 | c.1047_1048delinsG p.D349Efs*61 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | called by pindel, varscan2*
- NPHP1 | c.314dup p.E106Rfs*5 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, pindel, varscan2
- PIK3AP1 | c.358del p.H120Ifs*18 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- PRSS35 | c.874del p.E292Nfs*15 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- RBM15 | c.2313dup p.G772Wfs*38 | Frame Shift Ins (INS) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2880del p.C961Afs*14 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by pindel, varscan2
- ACSM5 | c.1717C>A p.R573= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV59374226; called by muse, mutect2
- AHDC1 | c.3471G>T p.T1157= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV55941810; called by muse, mutect2, varscan2
- ANKRD52 | c.2682G>T p.A894= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs368029714, COSV57287009; called by muse, mutect2, varscan2
- BRIX1 | c.720C>A p.L240= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57762270; called by muse, mutect2, varscan2
- C2CD3 | c.3420A>C p.V1140= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV58099223; called by muse, mutect2, varscan2
- C3orf22 | c.243G>T p.P81= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100559493, COSV100559530; called by muse, mutect2
- CSMD3 | c.8232T>C p.T2744= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV52291866; called by muse, mutect2, varscan2
- DLAT | c.798A>T p.V266= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV54773006; called by muse, mutect2, varscan2
- DLC1 | c.1776T>A p.S592= (on ENST00000276297 / NM_001348081.2; = p.S155= on NM_006094.5) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV52323717; called by muse, mutect2, varscan2
- ECPAS | c.5163C>G p.L1721= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52205703; called by muse, mutect2, varscan2
- EPB42 | c.1824C>T p.V608= (on ENST00000441366 / NM_001114134.2; = p.V638= on NM_000119.3) | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV55751235; called by muse, mutect2, varscan2
- EPX | c.1629G>A p.R543= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV56598772; called by muse, mutect2, varscan2
- FAM13A | c.3018G>T p.L1006= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV52011558; called by muse, mutect2, varscan2
- FCGBP | c.4389C>G p.L1463= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV55438340, COSV55451325; called by muse, mutect2, varscan2
- FCRL5 | c.468A>T p.A156= | Silent (SNP) | VAF 57/189 reads (30%) | catalogued as COSV62519165; called by muse, mutect2, varscan2
- FSIP2 | c.17295C>T p.P5765= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100555098; called by muse, mutect2, varscan2
- GPR6 | c.1056G>T p.V352= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV51573246; called by muse, mutect2, varscan2
- HARS2 | c.564C>T p.P188= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as rs777035084, COSV51227397; ClinVar: likely benign; called by muse, mutect2, varscan2
- HHAT | c.930C>G p.L310= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs1364790464, COSV54807509; called by muse, mutect2, varscan2
- HTR3B | c.642C>T p.S214= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV52747139; called by muse, mutect2, varscan2
- IL2RA | c.357G>T p.A119= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56922398; called by muse, varscan2
- INPPL1 | c.2169G>T p.G723= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV53358716; called by muse, mutect2, varscan2
- ITGAL | c.1182A>G p.P394= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV63323856; called by muse, mutect2, varscan2
- IVNS1ABP | c.1095G>A p.E365= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs1169305571, COSV62251909; called by muse, mutect2, varscan2
- KCND3 | c.864G>A p.T288= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs769635941, COSV56188117; called by muse, mutect2, varscan2
- KIAA0319 | c.1170G>A p.K390= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs1561990454, COSV65501629; called by muse, mutect2, varscan2
- MFSD14A | c.414G>A p.V138= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV64515063, COSV64515212; called by muse, mutect2, varscan2
- MLLT6 | c.1263G>A p.A421= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs765867436; called by muse, mutect2, varscan2
- MMP7 | c.543G>A p.A181= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs149122882; called by muse, mutect2, varscan2
- MROH7 | c.1789C>T p.L597= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs781677684, COSV59876774; called by muse, varscan2
- NAPG | c.811C>T p.L271= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV59798204; called by muse, mutect2, varscan2
- NDUFS8 | c.632G>A p.*211= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV55837136; called by muse, mutect2, varscan2
- NT5DC2 | c.573G>A p.P191= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs779866215, COSV58740150; called by muse, mutect2, varscan2
- NTSR2 | c.813C>A p.T271= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as COSV60992467; called by muse, mutect2, varscan2
- OR2T4 | c.711C>A p.L237= | Silent (SNP) | VAF 103/216 reads (48%) | catalogued as COSV63544944; called by muse, mutect2, varscan2
- OR52N1 | c.531C>A p.P177= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV57693272; called by muse, mutect2, varscan2
- OR8A1 | c.804C>A p.T268= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV52508816; called by muse, mutect2, varscan2
- PCDHB4 | c.2172C>T p.C724= | Silent (SNP) | VAF 40/227 reads (18%) | catalogued as COSV52026142; called by muse, mutect2, varscan2
- PIP4K2A | c.996C>T p.F332= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs749177271, COSV60540577; called by muse, mutect2, varscan2
- PSAPL1 | c.726C>A p.L242= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs779467471, COSV59843779, COSV59844294; called by muse, mutect2
- PTPRG | c.1284G>C p.R428= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV55649966, COSV55659447; called by muse, mutect2, varscan2
- RBM15 | c.294C>G p.L98= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV63924299; called by muse, mutect2, varscan2
- RGS12 | c.1737C>A p.I579= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs756639126, COSV60909161; called by muse, mutect2, varscan2
- RNF150 | c.954C>T p.C318= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60798181; called by muse, mutect2, varscan2
- RYR2 | c.11808A>G p.A3936= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV63708490; called by muse, mutect2, varscan2
- SEMA4A | c.948A>C p.T316= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV61773787; called by muse, mutect2, varscan2
- SLC22A11 | c.759G>T p.R253= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV57254741; called by muse, mutect2, varscan2
- SLFN13 | c.2049G>A p.K683= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs1458409966, COSV53195262; called by muse, mutect2, varscan2
- SLITRK1 | c.1020C>A p.P340= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV65677199; called by muse, mutect2, varscan2
- SLX4 | c.4686G>A p.P1562= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as rs752013105, COSV53567737; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPAM1 | c.828C>A p.L276= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV56146776; called by muse, mutect2, varscan2
- UNC13D | c.1569C>T p.S523= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV52886876; called by muse, mutect2, varscan2
- UNC5C | c.1518C>A p.T506= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV71661856; called by muse, mutect2, varscan2
- VWA3B | c.390C>T p.S130= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV68245030; called by muse, mutect2, varscan2
- ZNF804B | c.36C>G p.L12= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV60849574; called by muse, mutect2, varscan2
- ERCC8 | c.-1T>C | 5'UTR (SNP) | VAF 9/54 reads (17%) | catalogued as rs765931804, COSV99410376; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85651G>A | Intron (SNP) | VAF 13/116 reads (11%) | catalogued as COSV72282594; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11866C>T | Intron (SNP) | VAF 12/118 reads (10%) | catalogued as rs770396111, COSV100570943; called by muse, mutect2
- PPAN | c.292-80G>A | Intron (SNP) | VAF 19/89 reads (21%) | catalogued as rs993831679, COSV99461261; called by muse, mutect2, varscan2
- SSPOP | n.10457G>T | RNA (SNP) | VAF 7/25 reads (28%) | catalogued as COSV65135660; called by muse, mutect2, varscan2
